TCGA case TCGA-YZ-A980 — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: The Ohio State University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e00ce846-9a0e-48b5-be9f-84d443a0f78a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Alive.

Diagnoses (2)
1. Mixed epithelioid and spindle cell melanoma (the primary disease): ICD-O-3 morphology code: 8770/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 75.9 years (27,716 days); Year of diagnosis: 2010; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T3b; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T3b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,862 days (5.1 years); Sites of involvement: Eye, Choroid / Eye, Ciliary Body.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 14.
   Pathology details: Consistent pathology review: Yes; Epithelioid cell percent range: 1-30%; Extrascleral extension present: No; Measurement type: Pathologic; Spindle cell percent range: 61-90%; Tumor depth measurement: 9.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Subsequent primary of the skin of scalp and neck (histology not recorded by GDC). Age at diagnosis: 80.1 years (29,272 days); Days to diagnosis: 1,556 days (4.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 1,283 days (3.5 years); Disease response: Tumor Free.
- Days to follow up: 1,601 days (4.4 years); Disease response: Tumor Free.
- Days to follow up: 1,862 days (5.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 24.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 81.103 kg; Height: 177.8 cm; BMI: 25.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YZ-A980-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 90 mg.
  Slide TCGA-YZ-A980-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-YZ-A980-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YZ-A980-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology, Tumor tissue site list: Submitted tumor site: Ciliary body.
- Primary pathology, Tumor morphology list, Tumor morphology 1: Histologic diagnosis: Spindle Cell.
- Primary pathology, Tumor morphology list, Tumor morphology 2: Histologic diagnosis: Epithelioid Cell; Tumor morphology percentage: 1-30%.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness: 9 mm; Tumor thickness measurement: Pathologic Measurement.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Scalp; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,862 days; disease-specific survival: no event (censored), 1,862 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,556 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YZ-A980-01A-11D-A39V-01): tumor purity 0.46, ploidy 1.95, whole-genome doublings 0.
